Gene-level copy-number profile of tumor specimen ALCH-B21A-TTP1-A from ALCHEMIST case ALCH-B21A, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 66.8 years (24,389 days).
Specimen ALCH-B21A-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ed40e7a1-4307-4ecd-9a78-64438be4ffea.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B21A-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,229 have no estimate.
https://portal.gdc.cancer.gov/files/927c99e2-4cfb-4201-9205-7711f5e5caed

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 193; copy number 1: 1,416; copy number 2: 56,183; copy number 3: 549; copy number 4: 27; copy number 5: 5; copy number 6: 16; copy number 7: 5.

Homozygous deletions (total copy number 0; autosomes only): 176 genes in 36 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:916,865–982,093, 6 genes: LINC02593, SAMD11, NOC2L, KLHL17, PLEKHN1, PERM1.
- chr2:25,328,640–25,375,845, 2 genes (within-gene range 0–2): MIR1301, ARNILA.
- chr2:96,798,278–96,870,757, 6 genes (within-gene range 0–2): MIR3127, CNNM3-DT, CNNM3, ANKRD23, ANKRD39, SEMA4C.
- chr2:232,343,116–232,525,716, 13 genes (within-gene range 0–3): NRBF2P6, ECEL1P3, AC068134.3, ALPP, AC068134.1, ECEL1P2, ALPG, ECEL1P1, AC068134.2, DIS3L2P1, ALPI, ECEL1, PRSS56.
- chr3:195,908,076–195,913,986, 1 gene (within-gene range 0–2): TNK2-AS1.
- chr7:5,592,816–5,606,655, 1 gene: FSCN1.
- chr7:149,776,042–149,833,979, 1 gene: SSPOP.
- chr9:64,810,865–64,811,429, 1 gene: BNIP3P4.
- chr9:123,402,525–123,402,603, 1 gene (within-gene range 0–2): MIR601.
- chr10:5,498,697–5,499,570, 1 gene: CALML5.
- chr11:68,312,591–68,449,275, 1 gene: LRP5.
- chr11:70,467,856–71,252,577, 10 genes (within-gene range 0–2): SHANK2, AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2, Y_RNA, AP000590.1, SHANK2-AS3, MIR3664, AP003783.1.
- chr11:73,218,281–73,242,427, 2 genes: P2RY2, AP002761.4.
- chr11:77,066,961–77,215,241, 3 genes: CAPN5, OMP, MYO7A.
- chr12:122,834,453–122,862,961, 1 gene: HIP1R.
- chr14:92,905,697–93,138,465, 5 genes: LINC02287, CHGA, ITPK1, ITPK1-AS1, CYB5AP3.
- chr15:25,184,306–25,250,940, 37 genes (within-gene range 0–2): SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44.
- chr15:90,839,641–90,963,125, 10 genes: AC124248.1, RN7SL363P, FURIN, FES, MAN2A2, AC068831.3, HDDC3, UNC45A, RCCD1-AS1, RCCD1.
- chr16:3,069,523–3,069,651, 1 gene (within-gene range 0–2): RNU1-125P.
- chr16:83,899,115–83,966,332, 3 genes (within-gene range 0–2): MLYCD, AC009119.2, OSGIN1.
- chr16:89,906,157–89,938,761, 5 genes (within-gene range 0–1): AC092143.3, MC1R, AC092143.1, AC092143.2, TUBB3.
- chr17:2,755,705–3,037,741, 2 genes: RAP1GAP2, AC015921.1.
- chr17:3,510,502–3,696,240, 14 genes (within-gene range 0–2): TRPV3, TRPV1, AC027796.5, AC027796.3, AC027796.1, SHPK, AC027796.2, CTNS, AC027796.4, TAX1BP3, P2RX5-TAX1BP3, AC132942.1, EMC6, P2RX5.
- chr17:4,433,940–4,488,208, 2 genes: SPNS3, AC127521.1.
- chr17:30,702,504–30,702,775, 1 gene: RN7SL316P.
- chr17:30,724,982–30,727,564, 2 genes (within-gene range 0–2): AC127024.7, AC127024.3.
- chr19:405,445–507,833, 6 genes (within-gene range 0–1): C2CD4C, SHC2, RNA5SP462, ODF3L2, MADCAM1, AC005775.1.
- chr19:11,574,660–11,579,008, 1 gene (within-gene range 0–1): ACP5.
- chr20:3,190,350–3,245,382, 4 genes: DDRGK1, ITPA, SLC4A11, AL109976.1.
- chr20:3,667,965–3,707,128, 2 genes: ADAM33, SIGLEC1.
- chr20:31,605,283–31,723,989, 6 genes (within-gene range 0–2): ID1, MIR3193, COX4I2, BCL2L1, BCL2L1-AS1, ABALON.
- chr20:63,939,829–63,956,985, 4 genes (within-gene range 0–1): UCKL1, MIR1914, MIR647, UCKL1-AS1.
- chr20:64,073,181–64,327,972, 12 genes: RGS19, MIR6813, OPRL1, LKAAEAR1, AL121581.3, MYT1, NPBWR2, PCMTD2, AL137028.2, CICP4, LINC00266-1, AL137028.1.
- chr21:43,358,147–43,366,566, 2 genes: LINC01679, AP001046.1.
- chr21:43,719,094–43,812,567, 6 genes: PDXK, AP001052.1, CSTB, TMEM97P1, RRP1, AATBC.
- chr21:46,420,553–46,421,034, 1 gene (within-gene range 0–2): RPL18AP2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 26 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:22,428,838–22,531,157, 2 genes, copy number 5: ZBTB40, ZBTB40-IT1.
- chr4:7,758,714–7,939,926, 2 genes, copy number 5 (within-gene range 2–5): AFAP1, AC112254.1.
- chr9:64,817,870–64,836,341, 1 gene, copy number 5: AL359955.1.
- chr14:18,333,726–18,419,273, 4 genes, copy number 6: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6.
- chr16:1,826,941–1,884,294, 4 genes, copy number 7 (within-gene range 1–7): FAHD1, MEIOB, AL031722.1, LINC00254.
- chr16:2,339,150–2,426,699, 1 gene, copy number 7 (within-gene range 1–7): ABCA17P.
- chr21:10,413,477–13,120,807, 12 genes, copy number 6: BAGE2, AF254983.1, TPTE, CYCSP41, SLC25A15P4, AF254982.1, IGHV1OR21-1, AP001464.1, ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.

Autosomal genes at a single copy (total copy number 1): 1,360. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
